Gene-level copy-number profile of tumor specimen ALCH-B3H6-TTP1-A from ALCHEMIST case ALCH-B3H6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,817 days).
Specimen ALCH-B3H6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b5148fb5-7bf3-49e2-8c28-ef08011323f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3H6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/c6769175-b7a8-41df-a650-0c0a986f06d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 1,420; copy number 2: 55,863; copy number 3: 1,065; copy number 4: 12; copy number 5: 2; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,020,120–1,069,355, 4 genes: AGRN, AL645608.5, AL390719.1, AL645608.8.
- chr1:12,938,472–13,155,961, 11 genes (within-gene range 0–2): PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF34P, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26.
- chr8:7,414,855–7,463,674, 4 genes: DEFB4B, HSPD1P3, DEFB103B, SPAG11B.
- chr8:7,601,004–7,601,267, 1 gene: AC134684.1.
- chr17:2,054,154–2,063,241, 1 gene (within-gene range 0–2): HIC1.
- chr19:18,434,388–18,443,597, 2 genes (within-gene range 0–2): ISYNA1, AC010335.1.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–1): MIR4758.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:6,713,432–6,757,044, 1 gene, copy number 5: TENT4A.
- chr8:7,705,182–7,771,988, 7 genes, copy number 5–6: OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A10P.

Autosomal genes at a single copy (total copy number 1): 1,417. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
